Gene-level copy-number profile of tumor specimen HTMCP-03-06-02007-01B from CGCI case HTMCP-03-06-02007, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIB; Tumor grade: G3.
Specimen HTMCP-03-06-02007-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 5c93d5c7-7edd-46af-99b8-44ae1b1392dc.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-03-06-02007-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,240 have no estimate.
https://portal.gdc.cancer.gov/files/2c87cd9f-6278-4d4f-8c51-d43a914668fd

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 5; copy number 1: 766; copy number 2: 55,839; copy number 3: 1,682; copy number 4: 83; copy number 5: 7; copy number 8: 1.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:149,676,851–149,747,818, 2 genes (within-gene range 0–2): AC243772.3, RNU1-68P.
- chr2:91,747,940–91,748,986, 1 gene (within-gene range 0–1): KMT5AP2.
- chr7:57,014,285–57,020,273, 1 gene: SLC29A4P1.
- chr21:8,701,461–8,701,562, 1 gene: CR381572.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 8 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:68,717,311–68,717,795, 1 gene, copy number 8: AL513534.3.
- chr12:54,276,631–54,351,846, 7 genes, copy number 5 (within-gene range 2–5): AC078778.1, HNRNPA1, NFE2, COPZ1, RNU6-950P, MIR148B, RN7SL744P.

Autosomal genes at a single copy (total copy number 1): 754. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
